Somatic mutation profile of tumor specimen ALCH-B1TL-TTP1-A (aliquot ALCH-B1TL-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1TL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 65.1 years (23,771 days).
Specimen ALCH-B1TL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3fa5ed8-0c0a-4854-84bb-741e2ff72176.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1TL-NB1-A (Blood Derived Normal), aliquot ALCH-B1TL-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a65eff0b-66b5-495b-b51f-97177be3cb85

The open-access MAF lists 102 somatic variants for this specimen: 76 protein-altering or splice-affecting, 18 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 18, Nonsense Mutation 5, 5'UTR 3, Intron 3, Splice Region 1, Splice Site 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.112C>G p.R38G | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV101547190; called by muse, mutect2
- ANK2 | c.1651G>T p.E551* | Nonsense Mutation (SNP) | VAF 20/466 reads (4%) | catalogued as rs1445502811; called by muse, mutect2
- CATSPER1 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV56413791; called by muse, mutect2
- CLCN5 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV56585548; called by muse, mutect2
- CSMD3 | c.9719C>A p.S3240Y (on ENST00000297405 / NM_001363185.1; = p.S3071Y on NM_052900.3) | Missense Mutation (SNP) | VAF 18/455 reads (4%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.968); catalogued as COSV52154582; called by muse, mutect2
- DACH1 | c.2107C>T p.R703C (on ENST00000619232 / NM_001366712.1; = p.R449C on NM_004392.6) | Missense Mutation (SNP) | VAF 14/481 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57498842; called by muse, mutect2
- ENPP1 | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 11/355 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100719477; called by muse, mutect2
- GPR152 | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56888458; called by muse, mutect2
- HAS1 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.013); catalogued as rs1424967285; called by muse, mutect2
- HTR2C | c.881G>T p.R294I | Missense Mutation (SNP) | VAF 7/164 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.1); catalogued as COSV52209650; called by muse, mutect2
- KIAA1109 | c.2330C>G p.S777C | Missense Mutation (SNP) | VAF 18/449 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52692828; called by muse, mutect2
- NRP2 | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1186838471, COSV55935827; called by muse, mutect2
- NUP107 | c.1783C>A p.H595N | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.415); catalogued as rs1490207049, COSV104392039; called by muse, mutect2
- PCDHGB3 | c.1627A>T p.S543C | Missense Mutation (SNP) | VAF 18/323 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV53953709; called by muse, mutect2
- PFKL | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs746385697, COSV100826965; called by mutect2, varscan2
- RANBP2 | c.4187C>T p.T1396I | Missense Mutation (SNP) | VAF 32/644 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99313200; called by muse, mutect2
- RIMS2 | c.4609G>T p.G1537* (on ENST00000666250 / NM_001348490.2; = p.G1108* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/390 reads (8%) | catalogued as COSV51706738; called by muse, mutect2
- RP1 | c.3712G>T p.G1238C | Missense Mutation (SNP) | VAF 13/298 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV55120789; called by muse, mutect2
- SLC7A3 | c.1193C>A p.A398E | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53226599; called by muse, mutect2
- SRRM2 | c.5116A>G p.R1706G | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1483817314; called by muse, mutect2
- ABCC11 | c.1168T>A p.L390M | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.309); called by muse, mutect2
- AC100868.1 | c.703A>T p.I235F | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- ALDH1L1 | c.1102T>A p.C368S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.405); called by muse, mutect2
- ALG9 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 23/449 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- AQR | c.107A>G p.K36R | Missense Mutation (SNP) | VAF 14/299 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.05); called by muse, mutect2
- ARID5B | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 18/630 reads (3%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2
- ARMC4 | c.2129T>A p.V710D | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- C10orf71 | c.2246C>T p.T749I | Missense Mutation (SNP) | VAF 11/311 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2
- CATSPERG | c.2656A>C p.K886Q | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- CHD9 | c.4429A>C p.K1477Q | Missense Mutation (SNP) | VAF 11/259 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2
- CHRDL1 | c.985T>A p.F329I (on ENST00000372045; = p.F335I on NM_145234.4) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, mutect2
- CRACDL | c.2623G>T p.D875Y | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRISP1 | c.657C>A p.D219E | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2
- CRYBG3 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- CYP7A1 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 28/635 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- DCLK2 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH5 | c.3965C>T p.S1322L | Missense Mutation (SNP) | VAF 22/561 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- DNAJC19 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 32/724 reads (4%) | SIFT tolerated (0.83); PolyPhen benign (0.125); called by muse, mutect2
- DYNC2H1 | c.10812+1G>T p.X3604_splice | Splice Site (SNP) | VAF 19/437 reads (4%) | called by muse, mutect2
- ENOPH1 | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- ENPP1 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 10/278 reads (4%) | called by muse, mutect2
- F2 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 14/456 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- FAT4 | c.8185A>G p.S2729G | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- FHL5 | c.549T>A p.H183Q | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FOXP2 | c.2072C>G p.T691R | Missense Mutation (SNP) | VAF 15/318 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- GALNT2 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2
- HEPHL1 | c.526C>G p.P176A | Missense Mutation (SNP) | VAF 18/504 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.006); called by muse, mutect2
- KDM5D | c.4046A>T p.N1349I | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.123); called by muse, mutect2
- KIR2DL4 | c.873C>G p.I291M (on ENST00000396284; = p.I252M on NM_001080772.2) | Missense Mutation (SNP) | VAF 16/419 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2
- KIR3DL1 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 12/372 reads (3%) | called by muse, mutect2
- KREMEN1 | c.282G>A p.W94* (on ENST00000407188; = p.W96* on NM_032045.5) | Nonsense Mutation (SNP) | VAF 16/385 reads (4%) | called by muse, mutect2
- MALRD1 | c.2389C>A p.L797M | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- MYH13 | c.3575C>T p.T1192I | Missense Mutation (SNP) | VAF 15/350 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.114); called by muse, mutect2
- MYO9A | c.6029C>G p.P2010R | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.873); called by muse, mutect2
- MYPN | c.3325A>T p.N1109Y | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUGGC | c.1859G>C p.R620T | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.343); called by muse, mutect2
- OR8D2 | c.344T>A p.L115Q | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OXR1 | c.1414G>T p.G472W (on ENST00000442977 / NM_001198532.1; = p.G471W on NM_018002.3) | Missense Mutation (SNP) | VAF 12/382 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2
- PCDHGA3 | c.2415C>A p.N805K | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); called by muse, mutect2
- PRTG | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.112); called by muse, mutect2
- RIMS2 | c.4610G>T p.G1537V (on ENST00000666250 / NM_001348490.2; = p.G1108V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RP1 | c.3100C>T p.H1034Y | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- SCARA3 | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2
- SCN7A | c.649A>T p.I217F | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC35A3 | c.*146C>G | Splice Region (SNP) | VAF 6/135 reads (4%) | called by muse, mutect2
- SPATA31D1 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 30/593 reads (5%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.715); called by muse, mutect2
- SYT10 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SYT13 | c.99G>C p.M33I | Missense Mutation (SNP) | VAF 10/322 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- TPD52 | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- TTC19 | c.932A>T p.Q311L | Missense Mutation (SNP) | VAF 15/363 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.173); called by muse, mutect2
- VSTM1 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- ZDBF2 | c.6709A>G p.R2237G | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2
- ZNF256 | c.1506T>A p.H502Q | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.014); called by muse, mutect2
- ZNF577 | c.821T>G p.V274G | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.321); called by muse, mutect2
- ZNF865 | c.2847G>T p.E949D | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ZSCAN25 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- BEST3 | c.835C>T p.L279= | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- CSNK1A1L | c.183C>T p.S61= | Silent (SNP) | VAF 8/160 reads (5%) | catalogued as rs1205241740, COSV65790346; called by muse, mutect2
- DSE | c.1101G>A p.L367= | Silent (SNP) | VAF 14/296 reads (5%) | catalogued as rs1369213380; called by muse, mutect2
- EOGT | c.288T>G p.V96= | Silent (SNP) | VAF 16/334 reads (5%) | called by muse, mutect2
- GALR1 | c.318C>T p.F106= | Silent (SNP) | VAF 12/332 reads (4%) | called by muse, mutect2
- HTT | c.5625A>G p.G1875= | Silent (SNP) | VAF 10/284 reads (4%) | called by muse, mutect2
- KLHL41 | c.417A>T p.L139= | Silent (SNP) | VAF 11/268 reads (4%) | called by muse, mutect2
- KRTAP10-5 | c.246C>T p.S82= | Silent (SNP) | VAF 32/448 reads (7%) | called by muse, mutect2
- LIPE | c.1296G>T p.L432= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as COSV99734348; called by muse, mutect2
- NOSTRIN | c.168G>A p.L56= | Silent (SNP) | VAF 10/232 reads (4%) | catalogued as COSV58322866; called by muse, mutect2
- NPBWR2 | c.336C>T p.F112= | Silent (SNP) | VAF 7/130 reads (5%) | catalogued as rs138941629; called by muse, mutect2
- NWD1 | c.462C>T p.I154= | Silent (SNP) | VAF 7/150 reads (5%) | called by muse, mutect2
- PDHA2 | c.213C>A p.R71= | Silent (SNP) | VAF 19/204 reads (9%) | catalogued as COSV54778172; called by muse, mutect2
- SCNN1B | c.1422C>A p.V474= | Silent (SNP) | VAF 10/225 reads (4%) | called by muse, mutect2
- SPTA1 | c.2514C>A p.I838= | Silent (SNP) | VAF 31/689 reads (4%) | called by muse, mutect2
- TMEM86B | c.75G>A p.L25= | Silent (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- TTN | c.26898G>T p.V8966= (on ENST00000591111; = p.V8039= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2
- UPF1 | c.541C>T p.L181= | Silent (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- DACH2 | c.*69A>T | 3'UTR (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- FSHR | c.-43C>G | 5'UTR (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- NMT2 | c.-1G>T | 5'UTR (SNP) | VAF 6/111 reads (5%) | catalogued as COSV100975493, COSV65382244; called by muse, mutect2
- PIFO | c.-14C>T | 5'UTR (SNP) | VAF 12/231 reads (5%) | called by muse, mutect2
- PPFIA2 | c.1267-62T>C | Intron (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- SNORD115-9 | n.81C>A | RNA (SNP) | VAF 15/417 reads (4%) | called by muse, mutect2
- TECR | c.606+21G>A | Intron (SNP) | VAF 22/410 reads (5%) | called by muse, mutect2
- THUMPD2 | c.673-452A>C | Intron (SNP) | VAF 19/312 reads (6%) | called by muse, mutect2
